Somatic mutation profile of tumor specimen MP2PRT-PAUBBT-TMP1-A (aliquot MP2PRT-PAUBBT-TMP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PAUBBT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,250 days).
Specimen MP2PRT-PAUBBT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea376629-f36d-4bb0-8409-0a7f27dfb268.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUBBT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUBBT-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/935da068-40e9-4039-808f-4ed707e4a1ea

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 8, Silent 6, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.2033A>G p.Y678C | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.682); catalogued as rs1437551187; called by muse, mutect2
- HMCN1 | c.16894G>A p.A5632T | Missense Mutation (SNP) | VAF 139/307 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs372434876; called by muse, mutect2, varscan2
- NAT8 | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 46/614 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs567763204; called by muse, mutect2
- ZNF382 | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 30/324 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs375749236; called by muse, mutect2
- GREM2 | c.152A>C p.E51A | Missense Mutation (SNP) | VAF 42/970 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.211); called by muse, mutect2
- MBD3L2B | c.612G>A p.M204I | Missense Mutation (SNP) | VAF 46/843 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2
- MORC4 | c.1993C>A p.Q665K | Missense Mutation (SNP) | VAF 312/334 reads (93%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- MPV17L | c.515_516insAAGAC p.D172Efs*53 | Frame Shift Ins (INS) | VAF 186/542 reads (34%) | called by mutect2, pindel, varscan2
- PRR23A | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 88/943 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.103); called by muse, mutect2
- ACP7 | c.186C>T p.F62= | Silent (SNP) | VAF 62/780 reads (8%) | catalogued as rs150213319; called by muse, mutect2
- ANO3 | c.1113C>T p.R371= | Silent (SNP) | VAF 15/443 reads (3%) | called by muse, mutect2
- EFHD1 | c.309C>T p.D103= | Silent (SNP) | VAF 194/429 reads (45%) | catalogued as rs983959718, COSV51132622; called by muse, mutect2, varscan2
- FAT3 | c.12927G>C p.A4309= | Silent (SNP) | VAF 48/513 reads (9%) | catalogued as rs763573249; called by muse, mutect2
- PTGER1 | c.114G>A p.L38= | Silent (SNP) | VAF 87/1282 reads (7%) | called by muse, mutect2
- SLC6A5 | c.1824C>A p.G608= | Silent (SNP) | VAF 33/498 reads (7%) | catalogued as rs1217223125; called by muse, mutect2
